Gene-level copy-number profile of tumor specimen TARGET-10-PAUCDY-09A from TARGET case TARGET-10-PAUCDY, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 9.9 years (3,632 days).
Specimen TARGET-10-PAUCDY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.6fd30c83-d793-50e8-ad60-c6ea31f6b434.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PAUCDY-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 349 have no estimate.
https://portal.gdc.cancer.gov/files/2de00ccb-3a95-4a5d-9e0f-39c7ad4e6dbc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,389; copy number 1: 703; copy number 2: 56,518; copy number 3: 651; copy number 5: 5; copy number 6: 6; copy number 8: 2.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:67,660,155–67,661,013, 1 gene: HNRNPCP9.
- chr1:152,600,662–152,601,086, 1 gene: LCE3C.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 11 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:124,025,287–124,989,325, 6 genes, copy number 6 (within-gene range 2–6): CNTNAP5, MTND5P22, AC019159.2, AC019159.1, RNA5SP102, RNU6-259P.
- chr6:29,826,967–29,831,125, 2 genes, copy number 8: HLA-G, HCG4P8.
- chr22:37,339,583–37,427,445, 1 gene, copy number 5 (within-gene range 2–5): ELFN2.
- chr22:37,367,960–37,427,479, 2 genes, copy number 5 (within-gene range 2–5): ELFN2, Z94160.2.

Autosomal genes at a single copy (total copy number 1): 702. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
